Somatic mutation profile of tumor specimen BA2910D (aliquot aq-BA2910D) from BEATAML1.0 case 2261, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 79.5 years (29,036 days).
Specimen BA2910D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42edc140-788d-4fad-8400-15a509d2a682.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2021D (Solid Tissue Normal), aliquot aq-BA2021D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f897733-23cb-43bc-b808-92987592f25a

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Silent 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.1998G>C p.K666N | Missense Mutation (SNP) | VAF 121/255 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377023736, COSV59205777, COSV59205799; ClinVar: likely pathogenic; called by muse, varscan2
- CDH23 | c.2255dup p.V753Cfs*21 | Frame Shift Ins (INS) | VAF 22/78 reads (28%) | catalogued as rs34432586; called by pindel, varscan2
- CDH23 | c.6569G>A p.G2190D | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs371090961; called by muse, mutect2, varscan2
- LGR6 | c.2200G>A p.V734M (on ENST00000367278 / NM_001017403.1; = p.V682M on NM_021636.3) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747233640, COSV55150893; called by muse, mutect2, varscan2
- RHOD | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369125041; called by muse, varscan2
- ZNF575 | c.616G>A p.G206S | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs201519815; called by muse, varscan2
- CCNF | c.1522G>A p.V508I | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- KATNIP | c.3320C>A p.A1107D | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- KDM4A | c.574A>G p.M192V | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MORC2 | c.2582G>A p.S861N (on ENST00000397641 / NM_001303256.3; = p.S799N on NM_014941.3) | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PDZD2 | c.1666G>T p.E556* | Nonsense Mutation (SNP) | VAF 32/82 reads (39%) | called by muse, mutect2, varscan2
- PLCE1 | c.2096G>A p.G699D | Missense Mutation (SNP) | VAF 135/304 reads (44%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XPNPEP2 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.152); called by muse, mutect2
- CFTR | c.981A>G p.L327= | Silent (SNP) | VAF 93/222 reads (42%) | catalogued as rs200112521; called by muse, mutect2, varscan2
- LPIN2 | c.219A>G p.A73= | Silent (SNP) | VAF 131/302 reads (43%) | catalogued as rs1255017503; called by muse, mutect2, varscan2
